CCDI case PBBLGF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/4896b847-721b-46b4-8e96-5bf884042e5c

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Malignant peripheral nerve sheath tumor: ICD-O-3 morphology code: 9540/3; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 16.3 years (5,949 days).

Biospecimens (3 samples)
- Sample 0DBHZ3: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DBHZ7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DBHZD: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
